TCGA case TCGA-FG-5965 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2cfc07f3-a31c-41a2-a9e3-b708d2421a78

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 39 years; Vital status: Dead; Days to death: 1,120 days (3.1 years).

Diagnoses (3)
1. Mixed glioma (the primary disease): ICD-O-3 morphology code: 9382/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 39.0 years (14,249 days); Year of diagnosis: 2008; Tumor grade: G2; Prior treatment: No; First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 89 days; Days to treatment end: 133 days; Treatment dose: 5,400 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 790 days (2.2 years); Number of cycles: 6; Treatment dose: 9,500 mg; Treatment outcome: Treatment Ongoing; Route of administration: Oral.
   Recorded as not given: Antiseizure Treatment, preoperative; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.
2. Recurrence of diagnosis 1 (Mixed glioma). Age at diagnosis: 41.0 years (14,964 days); Days to diagnosis: 715 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 765 days (2.1 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site.
3. Recurrence of diagnosis 1 (Mixed glioma). Age at diagnosis: 41.8 years (15,284 days); Days to diagnosis: 1,035 days (2.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,069 days (2.9 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site.

Follow-up (6 entries)
- Day 259 (post adjuvant therapy): Karnofsky performance status: 90.
- Day 460 (prior to adjuvant therapy): ECOG performance status: 1.
- Day 715 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 715 days (2.0 years).
- Days to follow up: 979 days (2.7 years); Disease response: With Tumor.
- Day 1,035 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,035 days (2.8 years).
- Days to follow up: 1,120 days (3.1 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Seizure / Vision Changes.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FG-5965-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.8.
  Slide TCGA-FG-5965-01B-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-FG-5965-01B-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-FG-5965-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FG-5965-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Initial weight: 230 mg.
  Slide TCGA-FG-5965-02A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FG-5965-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-FG-5965-02B-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 20; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FG-5965-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligoastrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy; Tumor site: Supratentorial, Frontal Lobe; History seizures: Yes; History headaches: Yes; Symp changes mental status: No; Symp changes visual: Yes; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: No; Family history brain tumor: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Temodar; Therapy regimen: Progression.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form 1: Treatment outcome first course: Stable Disease; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: No; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome at TCGA followup: Stable Disease; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,120 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,120 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 715 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FG-5965-01B-11D-1892-01): tumor purity 0.58, ploidy 3.95, whole-genome doublings 1.
